Gene-level copy-number profile of tumor specimen TCGA-86-8075-01A from TCGA case TCGA-86-8075, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 66.8 years (24,402 days).
Specimen TCGA-86-8075-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.9909ef24-06e2-4fdc-ad8c-6a5a525552ed.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-86-8075-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4b032144-1934-49d2-abc9-349265408b33

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,003; copy number 2: 4,801; copy number 3: 15,095; copy number 4: 12,673; copy number 5: 7,696; copy number 6: 13,338; copy number 7: 2,826; copy number 8: 910; copy number 9: 1,061; copy number 10: 336; copy number 11: 70; copy number 12: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-86-8075-01A-11D-2237-01): tumor purity 0.3, ploidy 4.21, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 5,207 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,795,527–47,704,029, 367 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr1:47,761,132–47,820,237, 2 genes, copy number 7: AL691459.1, AC096541.1.
- chr1:193,473,224–194,198,708, 1 gene, copy number 7 (within-gene range 6–7): AL136456.1.
- chr1:194,188,967–201,534,784, 96 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr1:242,671,140–248,919,946, 193 genes, copy number 7 (broad region; genes not listed).
- chr3:166,160,021–192,767,764, 451 genes, copy number 8 (broad region; genes not listed).
- chr5:115,124,762–117,722,097, 49 genes, copy number 7: TRIM36, TRIM36-IT1, AC008494.2, PGGT1B, AC008494.3, AC008494.1, CCDC112, HMGN1P15, CTNNA1P1, AK3P4, AC008628.2, AC008628.1, CCT5P1, FEM1C, TICAM2, TMED7-TICAM2, AC010226.1, TMED7, AC008549.2, AC008549.1, H3P24, RNU2-49P, CDO1, ATG12, AP3S1, LINCADL, LVRN, DDX43P1, ARL14EPL, AC034236.1, AC034236.3, AC034236.2, COMMD10, RNU6-644P, HMGN2P27, AC018752.1, SEMA6A, SEMA6A-AS1, RPS14P8, SEMA6A-AS2, RPS17P2, LINC02214, AC010267.1, AC093534.1, AC093534.2, RPL35AP15, AC093295.1, LINC00992, AC114322.1.
- chr5:117,778,826–117,779,532, 1 gene, copy number 7: RPL7L1P4.
- chr6:167,607–37,499,893, 1,124 genes, copy number 7 (broad region; genes not listed).
- chr7:70,972–63,176,019, 1,086 genes, copy number 9–10 (broad region; genes not listed).
- chr9:91,563,091–91,950,228, 1 gene, copy number 8 (within-gene range 5–8): ROR2.
- chr9:92,000,087–93,320,572, 48 genes, copy number 8 (within-gene range 3–8): SPTLC1, AL391219.1, HSPE1P22, AL354751.3, MTATP6P29, MTCO3P29, MTND3P23, MTND4LP7, MTND4P15, AL354751.1, LINC00475, AL354751.2, BEND3P2, PRSS47, AL136097.2, IARS1, MIR3651, SNORA84, NOL8, CENPP, AL136097.1, OGN, OMD, ASPN, ECM2, MIR4670, AL157827.1, AL157827.2, IPPK, AL137074.1, BICD2, AL136981.3, AL136981.4, ANKRD19P, RNU6-714P, EEF1DP2, AL136981.2, ZNF484, AL136981.1, SNX18P2, ALOX15P2, FGD3, SUSD3, AL451065.1, CARD19, NINJ1, AL390760.1, WNK2.
- chr9:103,065,416–103,065,598, 1 gene, copy number 7: AL589823.1.
- chr9:105,694,541–108,703,092, 39 genes, copy number 7: TMEM38B, AL592437.1, DEPDC1P2, SLC25A6P5, LINC01505, AL732323.1, AL451140.1, MIR8081, AL512649.2, RN7SKP77, AL512649.1, RNA5SP292, ZNF462, AL807761.4, AL512593.1, AL807761.1, AL807761.2, AL807761.3, AL445487.1, RAD23B, LINC01509, AL359552.1, HMGN2P32, RNU6-492P, KLF4, AL389915.1, PPIAP88, RNU6-996P, RNU6-1064P, RN7SL659P, RPL36AP6, AL162389.1, RNA5SP293, RPS15AP27, AC068050.1, CHCHD4P2, AL353742.1, AL669983.1, AL358779.1.
- chr9:118,687,752–120,721,972, 11 genes, copy number 7–12: AL355592.1, LINC02578, TUBB4BP6, BRINP1, AC006288.1, LINC01613, AL441989.1, MIR147A, CDK5RAP2, MEGF9, AHCYP2.
- chr9:131,125,586–132,079,867, 23 genes, copy number 7 (within-gene range 4–7): NUP214, RNU6-881P, AL157938.2, AL157938.3, AL157938.1, FAM78A, AL157938.4, PLPP7, AL354855.1, PRRC2B, SNORD62A, SNORD62B, AL358781.1, POMT1, AL358781.2, UCK1, PRRT1B, RAPGEF1, RN7SL328P, EIF4A1P3, AL160271.1, AL160271.2, MED27.
- chr13:73,399,031–73,408,352, 2 genes, copy number 10: AL162376.1, MARK2P12.
- chr16:4,616,493–5,235,822, 32 genes, copy number 8 (within-gene range 6–8): MGRN1, RN7SL850P, AC023830.1, Metazoa_SRP, MIR6769A, NUDT16L1, ANKS3, AC020663.1, C16orf71, ZNF500, Metazoa_SRP, SEPTIN12, AC020663.4, SMIM22, AC020663.2, ROGDI, GLYR1, AC020663.3, UBN1, PPL, SEC14L5, NAGPA-AS1, NAGPA, ALG1, C16orf89, AC026458.1, EEF2KMT, AC026458.2, AC074051.3, ENPP7P14, AC074051.1, LINC02164.
- chr16:5,260,686–6,092,954, 9 genes, copy number 8: AC074051.2, RPS3AP48, SNRPCP20, NPM1P3, LINC01570, MIR8065, AC012175.1, AC009135.2, AC009135.1.
- chr16:20,309,574–21,657,473, 51 genes, copy number 8 (within-gene range 6–8): GP2, UMOD, PDILT, AC106796.1, ACSM5, AC137056.1, ACSM2A, AC137056.2, ACSM2B, AC141273.1, ACSM5P1, ACSM3, AC141273.3, AC141273.2, ACSM1, THUMPD1, AC004381.3, AC004381.4, AC004381.1, ERI2, RNU6-944P, REXO5, AC004381.2, DCUN1D3, LYRM1, DNAH3, AC008551.1, TMEM159, AF001550.1, ZP2, ANKS4B, CRYM, AF001550.2, CRYM-AS1, AC008740.1, SNX29P1, AC008740.2, NPIPB3, SMG1P3, MIR3680-1, AC005632.6, SLC7A5P2, AC005632.5, AC005632.2, AC005632.4, AC005632.1, METTL9, AC005632.3, IGSF6, RNU6-1005P, RNU6-196P.
- chr16:27,133,483–28,323,849, 27 genes, copy number 8: EEF1A1P38, LINC02129, KDM8, AC109449.1, NSMCE1, NSMCE1-DT, AC106739.1, IL4R, IL21R, IL21R-AS1, GTF3C1, KATNIP, AC002551.1, AC016597.1, AC016597.2, Y_RNA, GSG1L, RNU6-159P, RNU6-1241P, XPO6, TPRKBP2, AC136611.1, RNY1P10, GAPDHP35, AC138904.3, SBK1, AC138904.1.
- chr16:28,341,437–28,822,033, 34 genes, copy number 8: AC138904.2, NPIPB6, AC138894.3, EIF3CL, MIR6862-1, CDC37P2, AC138894.4, AC138894.2, AC138894.1, NPIPB7, CLN3, APOBR, IL27, NUPR1, AC020765.6, AC020765.1, AC020765.2, SGF29, SULT1A2, AC020765.3, AC020765.4, SULT1A1, AC020765.5, NPIPB8, AC145285.4, EIF3C, CDC37P1, MIR6862-2, AC145285.5, NPIPB9, AC145285.7, AC145285.2, AC145285.1, AC145285.3.
- chr16:48,244,300–50,734,041, 67 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr17:19,215,615–19,336,715, 1 gene, copy number 9 (within-gene range 2–9): EPN2.
- chr17:19,296,596–21,594,180, 128 genes, copy number 9 (broad region; genes not listed).
- chr18:47,390–9,134,345, 175 genes, copy number 7–11 (broad region; genes not listed).
- chr18:9,112,404–9,136,645, 2 genes, copy number 7: AP005899.1, NDUFV2-AS1.
- chr18:10,661,933–28,177,946, 291 genes, copy number 7–8 (broad region; genes not listed).
- chr18:30,713,275–37,762,131, 120 genes, copy number 8 (broad region; genes not listed).
- chr19:27,638,483–37,614,179, 335 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr21:10,328,411–20,828,622, 148 genes, copy number 10 (broad region; genes not listed).
- chr21:21,223,295–21,226,829, 1 gene, copy number 10: AP001136.1.
- chr22:41,045,497–50,801,309, 291 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,003. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
